Somatic mutation profile of tumor specimen TCGA-VW-A8FI-01A (aliquot TCGA-VW-A8FI-01A-11D-A36O-08) from TCGA case TCGA-VW-A8FI, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.8 years (24,411 days).
Specimen TCGA-VW-A8FI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd097a49-5c27-4e36-b2ec-d15ec286e66c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VW-A8FI-10A (Blood Derived Normal), aliquot TCGA-VW-A8FI-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c33fbaea-648f-478a-b786-444543182b1a

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Intron 2, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- AREL1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.964); catalogued as rs1301781208, COSV62666059; called by muse, mutect2, varscan2
- ARMH3 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as rs1383116155, COSV64232782; called by muse, mutect2, varscan2
- ASAP3 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs746655789, COSV100369100; called by muse, mutect2, varscan2
- ATXN7 | c.1442T>A p.L481Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as COSV99893583; called by muse, mutect2, varscan2
- CDC14B | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs371730723; called by muse, mutect2, varscan2
- CHST11 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100358873; called by muse, mutect2, varscan2
- CUBN | c.7251C>A p.D2417E | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as COSV100911872; called by muse, mutect2, varscan2
- DEFB112 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV59183009; called by muse, mutect2
- DHX30 | c.1074A>G p.I358M (on ENST00000445061 / NM_138615.3; = p.I319M on NM_014966.3) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs764406446, COSV99274482; called by muse, mutect2, varscan2
- DNAH9 | c.7073C>T p.T2358M | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs568542419, COSV99303154; called by muse, mutect2, varscan2
- ELK1 | c.210+2T>C p.X70_splice | Splice Site (SNP) | VAF 28/34 reads (82%) | catalogued as COSV99901802; called by muse, mutect2, varscan2
- FAM135A | c.2177G>A p.G726E (on ENST00000370479 / NM_001351599.1; = p.G513E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99525024; called by muse, mutect2, varscan2
- FCER1A | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100929233; called by muse, mutect2, varscan2
- FRY | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778573468, COSV100968683; called by muse, mutect2, varscan2
- GABRD | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1007549925, COSV66080106; called by muse, mutect2, varscan2
- GSDMC | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs369692449, COSV52695873, COSV52696298; called by muse, mutect2, varscan2
- GYS2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV99679311; called by muse, mutect2, varscan2
- KRTAP11-1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as rs199724044, COSV60095174; called by muse, mutect2, varscan2
- MAGEB6 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs369371623, COSV66872799, COSV66873459; called by muse, mutect2, varscan2
- MYF6 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); catalogued as COSV57351241, COSV99952624; called by muse, mutect2, varscan2
- NAA11 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV99727092; called by muse, mutect2, varscan2
- NUP155 | c.3952A>C p.K1318Q (on ENST00000231498 / NM_153485.3; = p.K1259Q on NM_004298.4) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV99192134; called by muse, mutect2
- OR2A25 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV101376319; called by muse, mutect2, varscan2
- OR4D9 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as COSV100259649; called by muse, mutect2, varscan2
- PCLO | c.11594G>A p.S3865N | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs779464982, COSV100426297; called by muse, mutect2, varscan2
- SORT1 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.329); catalogued as COSV99860389; called by muse, mutect2, varscan2
- SPDEF | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772048340, COSV65001691; called by muse, mutect2, varscan2
- TEC | c.1857A>G p.I619M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1247084546, COSV99972052; called by muse, mutect2, varscan2
- TMEM132D | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1280927732, COSV67160048; called by muse, mutect2, varscan2
- TP53 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as CM102507, COSV52661381, COSV52721872, COSV52783879; called by muse, varscan2
- TTN | c.6062G>A p.R2021Q (on ENST00000591111; = p.R1975Q on NM_003319.4) | Missense Mutation (SNP) | VAF 21/189 reads (11%) | PolyPhen probably damaging (0.996); catalogued as rs150884428, COSV59980473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFYVE26 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as rs1172160435, COSV100719958; called by muse, mutect2, varscan2
- ZNF521 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs765354548, COSV100831288, COSV64125724; called by muse, mutect2, varscan2
- NRIP1 | c.926del p.Q309Rfs*28 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- AMMECR1L | c.483T>C p.N161= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99761195; called by muse, mutect2, varscan2
- ATP2B2 | c.1266G>A p.T422= (on ENST00000352432; = p.T388= on NM_001683.5) | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs992479975, COSV59489328; called by muse, mutect2, varscan2
- CRTAC1 | c.1773G>A p.K591= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as rs1030953880, COSV100084858; called by muse, mutect2, varscan2
- MPP6 | c.1377G>A p.P459= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as rs139735308; called by muse, mutect2, varscan2
- MYBPC2 | c.138T>C p.T46= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100731510; called by muse, mutect2, varscan2
- NOS2 | c.3444G>A p.L1148= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100569431; called by muse, mutect2, varscan2
- NRROS | c.1137C>T p.T379= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs1057456191, COSV100145305; called by muse, mutect2, varscan2
- PCDHA5 | c.2064C>T p.P688= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100972037; called by muse, mutect2, varscan2
- RP1L1 | c.2142G>A p.Q714= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101222843; called by muse, mutect2, varscan2
- TONSL | c.609C>T p.R203= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs569775648, COSV101340115; called by muse, mutect2, varscan2
- TTN | c.39630C>T p.P13210= (on ENST00000591111; = p.P5786= on NM_003319.4) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100589363; called by muse, mutect2, varscan2
- URGCP | c.2223G>A p.Q741= (on ENST00000453200 / NM_001077663.3; = p.Q732= on NM_017920.4) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV56253790, COSV99786862; called by muse, mutect2, varscan2
- USP24 | c.5643G>A p.L1881= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1426196433, COSV99598600; called by muse, mutect2, varscan2
- ZDBF2 | c.1221T>C p.S407= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1307577275, COSV100984257; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5350G>C | Intron (SNP) | VAF 56/196 reads (29%) | catalogued as rs1433292548, COSV100446843; called by muse, mutect2
- NEBL-AS1 | chr10:21173780 G>A | 5'Flank (SNP) | VAF 16/29 reads (55%) | catalogued as COSV68841192; called by muse, mutect2, varscan2
- TRIM5 | c.895+76G>T | Intron (SNP) | VAF 20/64 reads (31%) | catalogued as rs575235627, COSV99999899; called by muse, mutect2, varscan2
